Somatic mutation profile of cancer-model specimen HCM-BROD-0348-C25-85N (3D Organoid, passage 7; aliquot HCM-BROD-0348-C25-85N-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0348-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 70.0 years (25,552 days).
Specimen HCM-BROD-0348-C25-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9554061e-4960-4300-bcb6-cf25c7a9ebf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0348-C25-10B (Blood Derived Normal), aliquot HCM-BROD-0348-C25-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c50c1a67-1b34-40f0-b85e-5d3c306b0a91

The open-access MAF lists 65 somatic variants for this specimen: 51 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 11, Nonsense Mutation 4, Frame Shift Del 3, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 386/813 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC109583.1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 248/731 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as rs1410163768, COSV59350317, COSV59350851; called by muse, mutect2, varscan2
- ATP10B | c.1655C>A p.T552N | Missense Mutation (SNP) | VAF 426/899 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV59147690; called by muse, mutect2, varscan2
- BBX | c.5A>C p.K2T | Missense Mutation (SNP) | VAF 143/430 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460720430; called by muse, mutect2, varscan2
- BDKRB1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 340/647 reads (53%) | catalogued as rs376804785; called by muse, mutect2, varscan2
- CBFA2T3 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 802/1238 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs774310781, COSV51922943, COSV51929210; called by muse, mutect2, varscan2
- CCZ1B | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 135/571 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191873912; called by muse, mutect2, varscan2
- CHRNB4 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 426/709 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1369287083; called by muse, mutect2, varscan2
- CRYBG2 | c.4483C>T p.R1495W | Missense Mutation (SNP) | VAF 252/748 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1365192082; called by muse, mutect2, varscan2
- DNAH10 | c.6163G>A p.E2055K (on ENST00000409039; = p.E1994K on NM_207437.3) | Missense Mutation (SNP) | VAF 316/975 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV68994631; called by muse, mutect2, varscan2
- ELFN2 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 311/1019 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs572323623; called by muse, mutect2, varscan2
- FSHR | c.1711G>T p.A571S | Missense Mutation (SNP) | VAF 485/748 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58622879; called by muse, mutect2, varscan2
- GALR1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 710/1405 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1173376603, COSV55316201; called by muse, mutect2, varscan2
- IDH1 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 456/703 reads (65%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.978); catalogued as rs777431979; called by muse, mutect2, varscan2
- IGHV3-20 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 272/414 reads (66%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.13); catalogued as rs544392556; called by muse, varscan2
- KALRN | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 216/748 reads (29%) | catalogued as COSV99561953; called by muse, varscan2
- KRT4 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 105/419 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs1260907872, COSV53406765; called by muse, mutect2, varscan2
- KRT76 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 204/651 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762654173; called by muse, mutect2, varscan2
- OR10G4 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 442/976 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs191928020, COSV57979339; called by muse, mutect2, varscan2
- SLC25A2 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 452/922 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53403819; called by muse, mutect2, varscan2
- SPTAN1 | c.6736G>T p.E2246* | Nonsense Mutation (SNP) | VAF 351/352 reads (100%) | catalogued as COSV63988347; called by muse, mutect2, varscan2
- TMIGD2 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 787/789 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs375257491; called by muse, mutect2, varscan2
- ZNF546 | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 263/589 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.866); catalogued as rs1471047681; called by muse, mutect2, varscan2
- ANKUB1 | c.522A>T p.K174N | Missense Mutation (SNP) | VAF 217/631 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- BRD9 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 545/1129 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C17orf98 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 379/1500 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDH7 | c.1739T>A p.I580N | Missense Mutation (SNP) | VAF 491/1004 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- COPS7A | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 344/818 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNA14 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 174/359 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- GPR119 | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 729/730 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- KIAA1109 | c.8251C>T p.Q2751* | Nonsense Mutation (SNP) | VAF 164/363 reads (45%) | called by muse, mutect2, varscan2
- MYBPH | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 928/929 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OLFM1 | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 388/390 reads (99%) | PolyPhen benign (0.038); called by muse, varscan2
- OR10J4 | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 210/717 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR5F1 | c.13A>T p.N5Y | Missense Mutation (SNP) | VAF 327/679 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OVCH1 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 300/640 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- PCNX1 | c.59del p.G20Afs*12 | Frame Shift Del (DEL) | VAF 308/730 reads (42%) | called by mutect2, pindel, varscan2
- POLR2B | c.2145T>A p.D715E | Missense Mutation (SNP) | VAF 152/306 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROBO1 | c.4092C>A p.S1364R | Missense Mutation (SNP) | VAF 476/716 reads (66%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RYR2 | c.11419G>A p.A3807T | Missense Mutation (SNP) | VAF 156/525 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SHANK1 | c.4325G>A p.R1442H | Missense Mutation (SNP) | VAF 725/762 reads (95%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 258/732 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.286); called by muse, varscan2
- TBC1D20 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 269/515 reads (52%) | SIFT tolerated (0.82); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TET2 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 299/597 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TFDP1 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 543/831 reads (65%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TG | c.17_30del p.E6Afs*25 | Frame Shift Del (DEL) | VAF 203/737 reads (28%) | called by mutect2, pindel, varscan2
- TP53 | c.125del p.D42Vfs*2 | Frame Shift Del (DEL) | VAF 468/634 reads (74%) | called by mutect2, pindel, varscan2
- TRAF7 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 598/947 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TWIST2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 582/901 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- WDCP | c.662C>A p.T221N | Missense Mutation (SNP) | VAF 241/723 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF837 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 692/744 reads (93%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- B4GALNT2 | c.1440G>A p.T480= | Silent (SNP) | VAF 465/1036 reads (45%) | catalogued as rs374447392; called by muse, mutect2, varscan2
- C1orf116 | c.1539C>T p.S513= | Silent (SNP) | VAF 376/597 reads (63%) | called by muse, mutect2, varscan2
- CFAP46 | c.3327C>T p.L1109= | Silent (SNP) | VAF 524/1132 reads (46%) | called by muse, mutect2, varscan2
- CNTN2 | c.1641C>T p.D547= | Silent (SNP) | VAF 287/932 reads (31%) | catalogued as rs150567846, COSV100085333; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTR9 | c.3132C>T p.D1044= | Silent (SNP) | VAF 352/773 reads (46%) | catalogued as rs759447696; called by muse, mutect2, varscan2
- NOS3 | c.264G>A p.A88= | Silent (SNP) | VAF 172/624 reads (28%) | catalogued as rs757296609, COSV52491633; called by muse, mutect2, varscan2
- RANBP2 | c.3399T>C p.T1133= | Silent (SNP) | VAF 229/654 reads (35%) | called by muse, mutect2, varscan2
- TECTA | c.1332C>T p.Y444= | Silent (SNP) | VAF 406/874 reads (46%) | catalogued as rs775483215, COSV50697721; called by muse, varscan2
- TECTA | c.1425G>A p.P475= | Silent (SNP) | VAF 444/926 reads (48%) | catalogued as rs149533095; ClinVar: likely benign; called by muse, varscan2
- TUSC1 | c.439C>A p.R147= | Silent (SNP) | VAF 627/627 reads (100%) | called by muse, mutect2, varscan2
- ZBTB40 | c.2385C>T p.P795= | Silent (SNP) | VAF 208/704 reads (30%) | catalogued as rs752184234; called by muse, varscan2
- PDE4C | c.243-4085G>C | Intron (SNP) | VAF 29/478 reads (6%) | called by muse, mutect2
- SHF | c.304-9254dup | Intron (INS) | VAF 249/882 reads (28%) | called by mutect2, pindel, varscan2
- TERT | c.-54C>A | 5'UTR (SNP) | VAF 712/1455 reads (49%) | catalogued as COSV57201157; called by muse, mutect2, varscan2
